Somatic mutation profile of tumor specimen BA2756D (aliquot aq-BA2756D) from BEATAML1.0 case 2169, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.7 years (25,457 days).
Specimen BA2756D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc725a35-df0d-40e4-b619-4b0fa9c337b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2105D (Solid Tissue Normal), aliquot aq-BA2105D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e01e6a2a-c50f-4478-ab9e-581244890dce

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Splice Site 2, Intron 1, 5'UTR 1, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 57/139 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS15 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318520551; called by muse, mutect2, varscan2
- EYS | c.6019C>A p.L2007M | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV65469421; called by muse, mutect2
- FLT3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV54046796; called by muse, mutect2, varscan2
- IZUMO1R | c.352C>T p.R118* (on ENST00000440961; = p.R125* on NM_001199206.3) | Nonsense Mutation (SNP) | VAF 35/62 reads (56%) | catalogued as rs190330179; called by muse, mutect2, varscan2
- MYL5 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as rs765244059, COSV59140296; called by muse, mutect2, varscan2
- MYO18A | c.3075G>A p.M1025I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62871791; called by muse, varscan2
- STRC | c.3794+1G>A p.X1265_splice | Splice Site (SNP) | VAF 59/235 reads (25%) | catalogued as rs777192662; called by muse, mutect2
- DNMT3A | c.1932_1936+5del p.X644_splice | Splice Site (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- DUOX2 | c.2852-4C>T | Splice Region (SNP) | VAF 124/289 reads (43%) | called by muse, mutect2, varscan2
- MORC4 | c.2428G>T p.V810F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2
- SMC3 | c.2099T>G p.L700R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MISP | c.2019C>T p.Y673= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs150909199; called by muse, mutect2, varscan2
- MUC22 | c.3678C>T p.T1226= | Silent (SNP) | VAF 98/208 reads (47%) | catalogued as rs1188534235; called by muse, mutect2, varscan2
- NPIPB4 | c.2007G>A p.P669= | Silent (SNP) | VAF 40/738 reads (5%) | catalogued as rs1446064600, COSV51255271; called by muse, mutect2
- GPR146 | c.-111C>T | 5'UTR (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- MAP4 | c.2000-13535T>A | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
